Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7AP, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7AP-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) POSTERIOR BLADDER NECK:
Smooth muscle and few distorted prostatic glands.
- (B) POSTERIOR BLADDER NECK #2, INK AT MARGIN:
Smooth muscle consistent with bladder neck tissue, no tumor present.
No prostatic glands present.
- (C) LEFT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN ONE OF SIX LYMPH NODES. (1/6)
METASTATIC FOCUS MEASURES 4.0 MM. EXTRANODAL EXTENSION PRESENT.
- (D) RIGHT PELVIC LYMPH NODES:
METASTATIC ADENOCARCINOMA IN ONE OF NINE LYMPH NODES. (1/9)
METASTATIC FOCUS MEASURES 4.0 MM. EXTRANODAL EXTENSION PRESENT.
- (E) PROSTATE AND SEMINAL VESICLES, BLACK STITCH MARKS LOCATION OF FROZEN:
Supplemental report to follow.

Entire report and diagnosis completed by

C&CF ICD-O-3
Adenocarcinoma, acinar
path 8140/3
Adenocarcinoma NOS
8140/3
Site Prostate NOS
C61-9
W8/22/13

GROSS DESCRIPTION

- (A) POSTERIOR BLADDER NECK – One piece of tan pink soft tissue unoriented (0.3 x 0.2 x 0.1 cm). Entirely submitted for frozen section diagnosis in A.
- (B) POSTERIOR BLADDER NECK #2; INK AT MARGIN – One piece of tan pink soft tissue (0.7 x 0.7 x 0.3 cm). The margin is designated by the surgeon with ink. Entirely submitted, en face, in B.
INK CODE: Black – margin designated by surgeon.
- (C) LEFT PELVIC LYMPH NODE – A (7.5 x 5.5 x 1.1 cm aggregate) of fibroadipose tissue. The tissue is dissected to reveal six possible lymph nodes ranging from (0.3 x 0.3 x 0.3 cm – 5.0 x 1.2 x 0.8 cm).
SECTION CODE: C1, C2, two possible lymph nodes, in each; C3-C5, one possible lymph node, serially sectioned; C6-C8, one possible lymph node, serially sectioned.
- (D) RIGHT PELVIC LYMPH NODE - A (7.5 x 5.5 x 1.1 cm aggregate) of fibroadipose tissue. The tissue is dissected to reveal eleven possible lymph nodes ranging from (0.3 x 0.2 x 0.1 cm – 3.0 x 1.5 x 0.7 cm).
SECTION CODE: D1, one possible lymph node; D2, D3, three possible lymph nodes, in each; D4, two possible lymph nodes; D5, D6, one possible lymph node, serially sectioned; D7, D8, one possible lymph node, serially sectioned.
- (E) PROSTATE AND SEMINAL VESICLES, BLACK STITCH MARKS LOCATION OF FROZEN - Supplemental report to follow.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 2 of 4]
[REDACTED]

Specimen Date/Time:

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(E) PROSTATE AND SEMINAL VESICLES (BLACK STITCH MARKS LOCATION OF FROZEN):

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5).

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

TUMOR INVADING RIGHT SEMINAL VESICLE AND PERIVESICULAR SOFT TISSUE.

TUMOR EXTENDING TO THE MARGIN OF RESECTION.

PERINEURAL AND LYMPHOVASCULAR INVASION PRESENT.

SEE PREVIOUS REPORT FOR THE DIAGNOSIS OF THE PELVIC LYMPH NODES.

COMMENT

The prostate gland contains a single focus of prostatic adenocarcinoma. The tumor is located in right anterolateral, right lateral, right posterolateral, right posterior, mid posterior and left posterior peripheral zone. The tumor focus measures 2.5 x 2.0 cm in the largest cross-sectional dimension and it is present in the three cross sections of the prostate, focally in the apex and extensively in the base region. The tumor exhibits multifocal extensive extraprostatic extension. At the site of extraprostatic extension, the margin of resection is free of tumor. The areas of extraprostatic extension include the right lateral surface, right posterior surface, right superior neurovascular bundle region and base (bladder neck) area. The tumor extensively invades the right seminal vesicle (extraprostatic portion) and focally perivesicular soft tissue. The tumor extends to the cauterized margin of resection on the anterior bladder neck. The added length of cauterized tumor at the margin is approximately 6.0 mm. Focal extension to the perivesicular cauterized margin cannot be unequivocally excluded.

Please refer to the previous report for the diagnosis of the lymph nodes.

GROSS DESCRIPTION

(E) PROSTATE AND SEMINAL VESICLES (BLACK STITCH MARKS LOCATION OF FROZEN) – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.1 x 3.2 x 3.4 cm, 35 grams, post-fixation) has the usual shape. The soft tissue present along the right posterolateral aspect of the prostate appears more abundant than along the left side. A nodule is palpated in the right base region. Serial cross sections after fixation demonstrate a firm area consistent with tumor in the right peripheral zone of the second and third cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: E1-E6, right seminal vesicle and segment of right vas deferens from the base towards the tip; E7-E11,

[page 4 of 4]
Specimen Date/Time:

left seminal vesicle and segment of left vas deferens from the base towards the tip; E12, E13, prostatic base, right border; E14-E17, prostatic base, right posterior border; E18-E22, prostatic base, central portion; E23, E24, prostatic base, left border; E25, E26, prostatic base, left posterior border; E27, apex anterior; E28, E29, apex left; E30, E31, apex posterior; E32, apex right; E33-E44, sections of the three cross sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (E20-22, 24, 25 and 28) and orange ink (E41 and 42) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

see attached 0115

HIP/IA Discrepancy		☒

Source: NCI Genomic Data Commons file f370edaf-8c3c-47be-a9b8-4edc8a753013 (TCGA-KK-A7AP.5B2E970F-CF58-4A8E-90FD-A1AA16C95142.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).